Somatic mutation profile of tumor specimen TCGA-AA-3967-01A (aliquot TCGA-AA-3967-01A-01W-1073-09) from TCGA case TCGA-AA-3967, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 77.3 years (28,216 days).
Specimen TCGA-AA-3967-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a98cef19-f5fb-40c1-84ec-4dac92f74164.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3967-10A (Blood Derived Normal), aliquot TCGA-AA-3967-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb878d71-1248-4a2c-a077-4c6437ef1d12

The open-access MAF lists 161 somatic variants for this specimen: 120 protein-altering or splice-affecting, 39 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 39, Nonsense Mutation 7, Splice Site 3, Frame Shift Ins 3, RNA 1, Intron 1, Translation Start Site 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 68/310 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs2853574, CM993803, COSV101036569; ClinVar: pathogenic; called by muse, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 24/27 reads (89%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 69/100 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG8 | c.1600C>A p.L534M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.544); catalogued as COSV99699447; called by muse, mutect2, varscan2
- ACAN | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747767483, COSV100717109; called by muse, mutect2
- AEBP1 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs137891711, COSV99788915; called by muse, mutect2, varscan2
- ANKRD52 | c.1877C>T p.T626M | Missense Mutation (SNP) | VAF 126/144 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs1328474467, COSV99921057; called by muse, mutect2, varscan2
- APBB3 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1192293317, COSV60054157; called by muse, mutect2, varscan2
- APC | c.4467_4468insAATA p.H1490Nfs*25 | Frame Shift Ins (INS) | VAF 24/121 reads (20%) | catalogued as COSV57334014, COSV57343226, COSV57371310; called by mutect2, pindel, varscan2
- ATP1A2 | c.3023G>A p.R1008Q | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs781023681, COSV63402063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAT2 | c.1158C>G p.H386Q | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV100302289; called by muse, mutect2, varscan2
- CABS1 | c.253T>C p.F85L | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99908952; called by muse, mutect2, varscan2
- CATSPERB | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773719104, COSV56430819; called by muse, mutect2, varscan2
- CCDC28A | c.80dup p.N27Kfs*7 | Frame Shift Ins (INS) | VAF 70/104 reads (67%) | catalogued as rs756347761; called by mutect2, varscan2
- CDH11 | c.1931A>G p.K644R | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT tolerated (0.47); PolyPhen probably damaging (1); catalogued as COSV51755967, COSV99217324; called by muse, mutect2, varscan2
- CDH2 | c.2110G>C p.D704H | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV99295803; called by muse, mutect2, varscan2
- CENPJ | c.2636C>T p.S879L | Missense Mutation (SNP) | VAF 16/603 reads (3%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV101121465; called by muse, mutect2
- CFAP65 | c.2371G>A p.G791S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs775364704, COSV58566638; called by muse, mutect2, varscan2
- CGNL1 | c.2467C>T p.R823C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as rs752242782, COSV55567252; called by muse, mutect2, varscan2
- COL15A1 | c.1954G>T p.G652* | Nonsense Mutation (SNP) | VAF 53/151 reads (35%) | catalogued as COSV100897437; called by muse, mutect2, varscan2
- CRISPLD1 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.853); catalogued as rs200273072, COSV100081439, COSV100081617; called by muse, mutect2, varscan2
- CSMD2 | c.2576-1G>T p.X859_splice | Splice Site (SNP) | VAF 39/105 reads (37%) | catalogued as COSV99586411; called by muse, mutect2, varscan2
- CUBN | c.6772C>T p.R2258C | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.677); catalogued as rs774125861, COSV100912096; called by muse, mutect2, varscan2
- DEDD | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs753790428, COSV100919030; called by muse, mutect2, varscan2
- DHX8 | c.1514T>A p.L505H | Missense Mutation (SNP) | VAF 119/272 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV99291942; called by muse, mutect2, varscan2
- DISP3 | c.3058G>A p.V1020I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs770679216, COSV53820529; called by muse, mutect2, varscan2
- DMGDH | c.1667C>A p.A556E | Missense Mutation (SNP) | VAF 52/84 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99668513; called by muse, mutect2, varscan2
- DNAH11 | c.2854C>T p.P952S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.03); catalogued as COSV60966588; called by muse, mutect2, varscan2
- DNAH3 | c.9872G>A p.R3291Q | Missense Mutation (SNP) | VAF 200/500 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761883403, COSV99765130; called by muse, mutect2, varscan2
- DNAH3 | c.3056C>T p.T1019M | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1051092511, COSV54525237; called by muse, mutect2, varscan2
- DNAH5 | c.10657C>T p.R3553W | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs754263109, COSV54218517, COSV99443101; called by muse, mutect2, varscan2
- DNER | c.2050C>T p.R684C | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs549129843, COSV59159704, COSV59170885; called by muse, mutect2, varscan2
- DTNA | c.876+1G>C p.X292_splice | Splice Site (SNP) | VAF 4/77 reads (5%) | catalogued as COSV99311055; called by muse, mutect2
- DYRK1A | c.1046G>A p.C349Y | Missense Mutation (SNP) | VAF 95/185 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100117486; called by muse, mutect2, varscan2
- FN1 | c.4570C>T p.R1524C | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs903709673, COSV60549378; called by muse, mutect2, varscan2
- GIMAP1 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 78/408 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs750341190, COSV100211941; called by muse, mutect2, varscan2
- GUCY1B1 | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774647698, COSV100025332; called by muse, mutect2
- HIVEP3 | c.1864G>T p.E622* | Nonsense Mutation (SNP) | VAF 66/162 reads (41%) | catalogued as COSV99911559; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.579G>T p.M193I (on ENST00000354667 / NM_031243.3; = p.M181I on NM_002137.4) | Missense Mutation (SNP) | VAF 113/333 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV61159279; called by muse, mutect2, varscan2
- HS2ST1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63350737; called by muse, mutect2, varscan2
- IDI2 | c.174G>C p.L58F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52988157; called by muse, mutect2, varscan2
- JMY | c.1893T>G p.I631M | Missense Mutation (SNP) | VAF 104/232 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.79); catalogued as COSV101267945; called by muse, mutect2, varscan2
- JUP | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs782435477, COSV100159342; called by muse, mutect2, varscan2
- KCNB1 | c.2102C>A p.A701D | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.003); catalogued as COSV100870389; called by muse, varscan2
- KCNJ1 | c.244A>T p.T82S | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV100131242; called by muse, mutect2, varscan2
- KERA | c.871C>T p.H291Y | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV57132081; called by muse, mutect2
- KERA | c.749C>T p.S250L | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV99899322; called by muse, mutect2
- KLHL11 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV100044191; called by muse, mutect2, varscan2
- LNP1 | c.205C>T p.H69Y | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV101051216; called by muse, mutect2, varscan2
- LPIN2 | c.2047G>A p.D683N | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99857988; called by mutect2, varscan2
- LRP1B | c.3133G>T p.E1045* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV101253032, COSV67233618; called by muse, mutect2, varscan2
- LUZP2 | c.719C>G p.P240R | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV61209960; called by muse, mutect2, varscan2
- LZTS1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs200343127, COSV99742700; called by mutect2, varscan2
- MAMDC2 | c.371G>T p.S124I | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101015246; called by muse, mutect2, varscan2
- MAP3K5 | c.3211G>A p.E1071K | Missense Mutation (SNP) | VAF 6/164 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV100752518; called by muse, mutect2
- MDN1 | c.8150T>C p.I2717T | Missense Mutation (SNP) | VAF 56/72 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV101020800; called by muse, mutect2, varscan2
- MNAT1 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs763740169, COSV99709805; called by muse, mutect2, varscan2
- MYOM3 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 83/423 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV100292496; called by muse, mutect2, varscan2
- NLRP7 | c.2240C>T p.T747M (on ENST00000340844 / NM_206828.3; = p.T719M on NM_139176.3) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs140486104; called by muse, mutect2, varscan2
- NPHP1 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | catalogued as COSV100337827; called by muse, mutect2, varscan2
- NUP210L | c.2802G>T p.E934D | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.051); catalogued as COSV99667300; called by muse, mutect2, varscan2
- OR5I1 | c.181A>T p.M61L | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV100041224; called by muse, mutect2
- PAM | c.2711C>T p.T904M (on ENST00000438793 / NM_001319943.1; = p.T905M on NM_000919.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs113740014; called by muse, mutect2, varscan2
- PANK3 | c.789G>T p.L263F | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53323323; called by muse, mutect2, varscan2
- PAXIP1 | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV68186255; called by muse, mutect2, varscan2
- PCDH15 | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57321053; called by muse, mutect2, varscan2
- PHF20L1 | c.1946C>T p.T649M | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs767149884, COSV55198624; called by muse, mutect2, varscan2
- PIGM | c.861T>G p.S287R | Missense Mutation (SNP) | VAF 153/404 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV100928007; called by muse, mutect2, varscan2
- PPP4R3A | c.1510C>T p.Q504* (on ENST00000554943 / NM_001366432.1; = p.Q491* on NM_001284280.1) | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV61504902; called by muse, mutect2, varscan2
- PREX2 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746227590, COSV55795364, COSV55806119; called by muse, mutect2, varscan2
- PRMT7 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 112/284 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756734451, COSV59833244; called by muse, mutect2, varscan2
- PYHIN1 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs193920831, COSV63721562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- QRICH2 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.133); catalogued as rs147255233; called by muse, mutect2, varscan2
- RBL2 | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.357); catalogued as rs139520629; called by muse, mutect2, varscan2
- RGS22 | c.2113C>A p.Q705K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as COSV62662441; called by muse, mutect2, varscan2
- RHBDF1 | c.1637C>T p.S546F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1422604952, COSV99244281; called by muse, mutect2, varscan2
- ROBO1 | c.2798C>T p.A933V | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs1007241533, COSV71392121; called by muse, mutect2, varscan2
- SALL1 | c.2270G>A p.R757H | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755216623, COSV99171581; called by muse, mutect2, varscan2
- SALL1 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 89/222 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs779513054, COSV51763776; called by muse, mutect2, varscan2
- SERINC2 | c.912C>A p.N304K (on ENST00000373709 / NM_178865.5; = p.N308K on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); catalogued as COSV101036736, COSV65489351; called by muse, mutect2, varscan2
- SF3B1 | c.2768A>G p.K923R | Missense Mutation (SNP) | VAF 79/198 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1172302608, COSV100133876; called by muse, mutect2, varscan2
- SGCE | c.1334C>T p.T445I (on ENST00000647096; = p.T409I on NM_003919.3) | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs545029310, COSV99722187; called by muse, mutect2, varscan2
- SIGLEC1 | c.2773G>C p.G925R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV52465063; called by muse, mutect2
- SLC11A1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51917370; called by muse, mutect2, varscan2
- SLC12A6 | c.2078C>T p.A693V (on ENST00000354181 / NM_001365088.1; = p.A642V on NM_005135.2) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.369); catalogued as COSV51626638; called by muse, mutect2, varscan2
- SLC25A28 | c.854G>T p.C285F | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100979599; called by muse, mutect2, varscan2
- SLFNL1 | c.797G>A p.G266D | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1319645112, COSV100262802; called by muse, mutect2, varscan2
- SMC2 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 73/148 reads (49%) | catalogued as COSV99658425; called by muse, mutect2, varscan2
- SNTG1 | c.206G>C p.G69A | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52442173, COSV52447090; called by muse, mutect2, varscan2
- SNURF | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.976); catalogued as COSV100577904, COSV57601108; called by muse, mutect2, varscan2
- SPATS2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 82/95 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100423373; called by muse, mutect2, varscan2
- SQSTM1 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs778537429, COSV100657637; called by muse, mutect2, varscan2
- SRRM3 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as rs370360717, COSV58388319; called by muse, mutect2
- STOX2 | c.2569G>A p.G857R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57852644; called by muse, mutect2, varscan2
- TADA1 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV63310271, COSV63310723; called by muse, mutect2
- TARS2 | c.995A>G p.Y332C | Missense Mutation (SNP) | VAF 143/254 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1425721685, COSV100945859; called by muse, mutect2, varscan2
- TBC1D12 | c.1333G>T p.E445* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99831181; called by muse, mutect2, varscan2
- TBX2 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99538639, COSV99538708; called by muse, mutect2, varscan2
- TCERG1 | c.2971A>T p.I991F | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as COSV99694443; called by muse, mutect2, varscan2
- TEX13B | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 10/296 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV57202922; called by muse, mutect2
- TGIF2LY | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 78/98 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58291604; called by muse, mutect2, varscan2
- TMEM106C | c.644T>G p.V215G | Missense Mutation (SNP) | VAF 41/270 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56742818, COSV99873611; called by muse, mutect2, varscan2
- TMEM74B | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 96/170 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs368653757; called by muse, mutect2, varscan2
- TNC | c.4909C>T p.R1637C | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as COSV100405037; called by muse, mutect2, varscan2
- TSHZ3 | c.2402G>T p.C801F | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as COSV53663493; called by muse, mutect2, varscan2
- TSPAN12 | c.502T>A p.W168R | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99763021; called by muse, mutect2, varscan2
- TTN | c.41548G>A p.E13850K (on ENST00000591111; = p.E6426K on NM_003319.4) | Missense Mutation (SNP) | VAF 10/190 reads (5%) | PolyPhen possibly damaging (0.73); catalogued as COSV100595807; called by muse, mutect2
- TTN | c.2249C>A p.P750H (on ENST00000591111; = p.P704H on NM_003319.4) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | PolyPhen probably damaging (0.997); catalogued as COSV100595811, COSV60228416; called by muse, mutect2
- UNKL | c.1931G>A p.G644D (on ENST00000389221 / NM_001372107.1; = p.G140D on NM_001276414.2) | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.709); catalogued as COSV99201403; called by muse, mutect2, varscan2
- WNT7A | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs773943599, COSV99540936; called by muse, mutect2, varscan2
- ZNF292 | c.4348G>C p.D1450H | Missense Mutation (SNP) | VAF 143/196 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100369821; called by muse, mutect2, varscan2
- ZNF335 | c.956-1G>A p.X319_splice | Splice Site (SNP) | VAF 23/31 reads (74%) | catalogued as COSV100532666; called by muse, mutect2, varscan2
- ZNF560 | c.1699G>A p.A567T | Missense Mutation (SNP) | VAF 180/221 reads (81%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142348936; called by muse, mutect2, varscan2
- ZNF578 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 133/398 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as COSV69736606; called by muse, varscan2
- ZSWIM3 | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs780067523, COSV54851963; called by muse, mutect2, varscan2
- CDH8 | c.1487_1498del p.F496_E499del | In Frame Del (DEL) | VAF 28/187 reads (15%) | called by mutect2, pindel, varscan2
- COLEC12 | c.1823del p.P608Rfs*38 | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | called by mutect2, pindel, varscan2
- MRC1 | c.2258G>C p.C753S | Missense Mutation (SNP) | VAF 101/406 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSBPL10 | c.1889_1895dup p.G633Ffs*24 | Frame Shift Ins (INS) | VAF 51/134 reads (38%) | called by mutect2, varscan2
- XKR3 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ASH1L | c.8238C>T p.L2746= (on ENST00000368346 / NM_001366177.2; = p.L2741= on NM_018489.3) | Silent (SNP) | VAF 22/324 reads (7%) | catalogued as COSV64206504; called by muse, mutect2
- ATP11A | c.1389C>T p.N463= | Silent (SNP) | VAF 18/230 reads (8%) | catalogued as rs201730815, COSV52113062; called by muse, mutect2
- ATP13A2 | c.435G>A p.T145= | Silent (SNP) | VAF 44/100 reads (44%) | catalogued as rs201154350, COSV100453930; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP9B | c.1659C>T p.N553= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as rs148663973; called by muse, mutect2, varscan2
- CCDC180 | c.3912G>A p.P1304= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as rs891195030, COSV100826576; called by muse, mutect2, varscan2
- CDC45 | c.1554G>A p.R518= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV54245731; called by muse, mutect2, varscan2
- CNTN6 | c.1515A>G p.P505= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV100610102; called by muse, mutect2, varscan2
- CSMD2 | c.5334G>T p.V1778= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99586406; called by muse, mutect2, varscan2
- DNAH5 | c.4686C>T p.F1562= | Silent (SNP) | VAF 112/242 reads (46%) | catalogued as rs751766956, COSV54216630; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNASE1L1 | c.684C>T p.R228= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs782064221, COSV50010057; called by muse, mutect2, varscan2
- FER1L6 | c.279C>T p.R93= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV101205492; called by muse, mutect2, varscan2
- FHOD3 | c.3897G>A p.Q1299= (on ENST00000359247 / NM_001281739.3; = p.Q1316= on NM_025135.5) | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV57164857, COSV99940231; called by muse, mutect2, varscan2
- GNL3L | c.1437C>T p.T479= | Silent (SNP) | VAF 315/356 reads (88%) | catalogued as COSV100328155; called by muse, mutect2, varscan2
- GRM6 | c.1632C>T p.D544= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs139758482; called by muse, mutect2, varscan2
- HDX | c.210A>T p.T70= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV99946661; called by muse, mutect2
- HECW1 | c.1725C>T p.G575= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs771700017, COSV67826506; called by muse, mutect2, varscan2
- IFT80 | c.1053G>T p.T351= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100424401; called by muse, mutect2, varscan2
- ITIH6 | c.1374G>A p.A458= | Silent (SNP) | VAF 70/83 reads (84%) | catalogued as rs147115871, COSV54489260; called by muse, mutect2, varscan2
- LRP1B | c.2973C>T p.D991= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as rs745554983, COSV67196448; called by muse, mutect2, varscan2
- MTUS2 | c.3039C>A p.G1013= | Silent (SNP) | VAF 27/30 reads (90%) | catalogued as rs775868363, COSV70916500, COSV70922868; called by muse, mutect2, varscan2
- NAALAD2 | c.966C>A p.G322= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100428065; called by muse, mutect2, varscan2
- OR2T3 | c.937A>C p.R313= | Silent (SNP) | VAF 83/1036 reads (8%) | catalogued as COSV62083057, COSV62083737; called by muse, mutect2
- OR52J3 | c.762C>A p.I254= | Silent (SNP) | VAF 96/352 reads (27%) | catalogued as COSV66746680, COSV66747476; called by muse, mutect2, varscan2
- PAN2 | c.105G>A p.Q35= | Silent (SNP) | VAF 95/124 reads (77%) | catalogued as COSV99228112; called by muse, mutect2, varscan2
- PCDH17 | c.601C>T p.L201= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100931444; called by muse, mutect2, varscan2
- PCDHA13 | c.1974G>A p.A658= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV56492153; called by muse, mutect2, varscan2
- PRPF8 | c.5331C>T p.I1777= | Silent (SNP) | VAF 11/203 reads (5%) | catalogued as COSV100517164; called by muse, mutect2
- PSAP | c.1089G>A p.T363= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as rs1307052772, COSV56455979; called by muse, mutect2, varscan2
- SAG | c.468C>T p.F156= | Silent (SNP) | VAF 236/534 reads (44%) | catalogued as rs375593027; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- SFSWAP | c.1536C>T p.G512= | Silent (SNP) | VAF 45/59 reads (76%) | catalogued as rs1232358326, COSV55527237; called by muse, mutect2, varscan2
- SH3GL3 | c.582G>A p.K194= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100195955; called by muse, mutect2, varscan2
- SLC12A6 | c.2199G>T p.L733= (on ENST00000354181 / NM_001365088.1; = p.L682= on NM_005135.2) | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV51626630; called by muse, mutect2, varscan2
- THSD7A | c.3339T>C p.N1113= | Silent (SNP) | VAF 56/520 reads (11%) | catalogued as COSV101448554; called by muse, mutect2, varscan2
- TTI1 | c.3213C>T p.S1071= | Silent (SNP) | VAF 28/42 reads (67%) | catalogued as rs1489990067, COSV100989581; called by muse, mutect2, varscan2
- TTN | c.41790G>A p.K13930= (on ENST00000591111; = p.K6506= on NM_003319.4) | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV60292390; called by muse, mutect2
- ZNF423 | c.2940G>A p.L980= (on ENST00000563137 / NM_001379286.1; = p.L972= on NM_015069.4) | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV52175668; called by muse, mutect2, varscan2
- ZNF549 | c.219G>A p.E73= (on ENST00000376233 / NM_001199295.2; = p.E60= on NM_153263.2) | Silent (SNP) | VAF 9/275 reads (3%) | catalogued as COSV99558376; called by muse, mutect2
- ZNF565 | c.1245C>T p.H415= (on ENST00000355114; = p.H375= on NM_152477.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 45/366 reads (12%) | catalogued as rs761333089, COSV58410590; called by muse, mutect2, varscan2
- ZNF569 | c.711T>C p.S237= | Silent (SNP) | VAF 115/243 reads (47%) | catalogued as COSV100386234; called by muse, mutect2, varscan2
- GCNT2 | c.926-34558G>A | Intron (SNP) | VAF 191/244 reads (78%) | catalogued as rs747525414, COSV99399086; called by muse, mutect2, varscan2
- RPS26P15 | n.155A>G | RNA (SNP) | VAF 49/157 reads (31%) | called by muse, mutect2, varscan2
